Somatic mutation profile of tumor specimen TCGA-91-6828-01A (aliquot TCGA-91-6828-01A-11D-1855-08) from TCGA case TCGA-91-6828, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 70.8 years (25,870 days).
Specimen TCGA-91-6828-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c879bb59-2ee5-416b-ae16-95e8efd30d34.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-91-6828-10A (Blood Derived Normal), aliquot TCGA-91-6828-10A-01D-1855-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b46d0c18-28dc-42fc-a599-04cfc4ac247a

The open-access MAF lists 290 somatic variants for this specimen: 235 protein-altering or splice-affecting, 51 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 198, Silent 51, Nonsense Mutation 17, Frame Shift Del 11, Splice Site 3, Frame Shift Ins 3, Splice Region 2, Nonstop Mutation 1, RNA 1, 3'Flank 1, 5'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 16/34 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- A2M | c.3102G>T p.R1034S | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.068); catalogued as COSV100588363, COSV59389951; called by muse, mutect2, varscan2
- AATK | c.2914G>C p.G972R (on ENST00000326724 / NM_001080395.3; = p.G869R on NM_004920.2) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV100352561; called by muse, mutect2, varscan2
- ABCA13 | c.5621C>G p.S1874* | Nonsense Mutation (SNP) | VAF 10/83 reads (12%) | catalogued as COSV70037022; called by muse, mutect2, varscan2
- ABCC9 | c.627G>C p.Q209H | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV53979539; called by muse, mutect2, varscan2
- ABHD2 | c.455A>G p.K152R | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV61775300; called by muse, mutect2, varscan2
- ABI3BP | c.652G>T p.V218L | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.452); catalogued as COSV52544495; called by muse, mutect2, varscan2
- ACAD8 | c.1027G>T p.E343* | Nonsense Mutation (SNP) | VAF 16/48 reads (33%) | catalogued as COSV55538985, COSV55541591; called by muse, mutect2, varscan2
- ACTR1B | c.161G>T p.G54V | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56705113; called by muse, mutect2, varscan2
- ADAM28 | c.967G>A p.V323I | Missense Mutation (SNP) | VAF 112/214 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV56103022; called by muse, mutect2, varscan2
- ADAMTS16 | c.1374G>A p.M458I | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56999025; called by muse, mutect2
- ADAMTSL1 | c.4921G>A p.G1641S | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.255); catalogued as COSV65884361; called by muse, mutect2, varscan2
- ADGRB3 | c.2009G>A p.G670E | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65408448; called by muse, mutect2
- ADGRE3 | c.1575G>C p.L525F | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.111); catalogued as COSV53730432; called by muse, mutect2, varscan2
- ADGRL2 | c.4115A>T p.Y1372F (on ENST00000370717 / NM_001366005.1; = p.Y1316F on NM_012302.4) | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV54678172; called by muse, mutect2
- ADGRL3 | c.2090G>A p.R697H (on ENST00000506720 / NM_001322402.2; = p.R629H on NM_015236.6) | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs921791162, COSV72231313; called by muse, mutect2, varscan2
- AKAP6 | c.5083G>A p.D1695N | Missense Mutation (SNP) | VAF 8/151 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as rs866570358, COSV55223549, COSV55229814; called by muse, mutect2
- ALDH1B1 | c.593C>A p.P198Q | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV66620268; called by muse, mutect2, varscan2
- ALG11 | c.439T>G p.F147V | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV101584257; called by muse, mutect2
- AMBRA1 | c.2929C>T p.Q977* (on ENST00000458649 / NM_001367468.1; = p.Q887* on NM_017749.3 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 8/29 reads (28%) | catalogued as COSV54058787; called by muse, mutect2, varscan2
- ANKRD26 | c.664A>C p.K222Q | Missense Mutation (SNP) | VAF 41/175 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.246); catalogued as COSV63091948; called by muse, mutect2, varscan2
- ANKRD34B | c.779G>T p.R260I | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as COSV58614264; called by muse, mutect2, varscan2
- AQP12B | c.158G>T p.G53V (on ENST00000621682; = p.G65V on NM_001102467.2) | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV68184217; called by muse, mutect2, varscan2
- ARAP1 | c.1080del p.F360Lfs*31 (on ENST00000393609 / NM_001040118.2; = p.F115Lfs*31 on NM_015242.4) | Frame Shift Del (DEL) | VAF 32/137 reads (23%) | catalogued as COSV100502265; called by mutect2, pindel, varscan2
- ARHGAP11A | c.245C>A p.T82N | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64381379; called by muse, mutect2
- ASB17 | c.542T>C p.I181T | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.043); catalogued as COSV99407829; called by muse, mutect2, varscan2
- ASXL3 | c.4230C>A p.H1410Q | Missense Mutation (SNP) | VAF 51/223 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as COSV52473236; called by muse, mutect2, varscan2
- ATL1 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CM092581, COSV63297027; called by muse, mutect2, varscan2
- ATP13A1 | c.2444G>T p.G815V | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as COSV52289109; called by muse, mutect2, varscan2
- BEND6 | c.283T>A p.L95M | Missense Mutation (SNP) | VAF 24/316 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV66069652; called by muse, mutect2
- BMT2 | c.691G>A p.D231N | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.096); catalogued as COSV99774469; called by muse, mutect2, varscan2
- BOC | c.2471C>A p.P824Q | Missense Mutation (SNP) | VAF 75/270 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); catalogued as COSV56355024; called by muse, mutect2, varscan2
- BPTF | c.1975G>T p.G659W | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV100074279; called by muse, mutect2, varscan2
- BRINP3 | c.2125C>A p.R709S | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV66532839; called by muse, mutect2, varscan2
- CACNA1B | c.634G>T p.V212L | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.815); catalogued as COSV53138147; called by muse, mutect2, varscan2
- CACNB2 | c.659C>A p.P220H (on ENST00000324631 / NM_201596.3; = p.P165H on NM_000724.4) | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV56637069, COSV99993079; called by muse, varscan2
- CADM1 | c.1133G>T p.G378V | Missense Mutation (SNP) | VAF 10/149 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59017047; called by muse, mutect2
- CASS4 | c.817C>A p.P273T | Missense Mutation (SNP) | VAF 38/235 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV100824564; called by muse, mutect2, varscan2
- CASS4 | c.818C>A p.P273H | Missense Mutation (SNP) | VAF 38/239 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100824565; called by muse, mutect2, varscan2
- CD1D | c.791G>T p.R264L | Missense Mutation (SNP) | VAF 54/155 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.594); catalogued as COSV63809502; called by muse, mutect2, varscan2
- CDH10 | c.341C>A p.T114K | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.843); catalogued as COSV52589334; called by muse, mutect2, varscan2
- CDKAL1 | c.1147G>C p.E383Q | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV51186929; called by muse, mutect2, varscan2
- CELF4 | c.1087C>A p.H363N | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.449); catalogued as COSV58460308; called by muse, mutect2, varscan2
- CFAP47 | c.1403G>T p.G468V | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT tolerated (0.3); PolyPhen benign (0.205); catalogued as COSV99934545; called by muse, mutect2, varscan2
- CHFR | c.754G>T p.D252Y (on ENST00000432561 / NM_001161345.1; = p.D211Y on NM_018223.2) | Missense Mutation (SNP) | VAF 44/161 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV57176474; called by muse, mutect2, varscan2
- CLDN4 | c.176C>T p.T59I | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV52896635; called by muse, mutect2, varscan2
- CLK2 | c.629A>G p.N210S (on ENST00000368361 / NM_001294339.2; = p.N209S on NM_003993.4) | Missense Mutation (SNP) | VAF 92/225 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.412); catalogued as rs1310022416, COSV62877808; called by muse, mutect2, varscan2
- COL28A1 | c.1661G>T p.G554V | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV68082130, COSV68083509; called by muse, mutect2, varscan2
- COL4A1 | c.4553A>T p.D1518V | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65428910; called by muse, mutect2
- COL4A1 | c.359del p.P120Qfs*36 | Frame Shift Del (DEL) | VAF 52/271 reads (19%) | catalogued as rs1566378788, COSV65422277; called by mutect2, pindel, varscan2
- CPA2 | c.668C>A p.P223H | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55980698; called by muse, mutect2, varscan2
- CSNK1G3 | c.293G>T p.G98V | Missense Mutation (SNP) | VAF 9/196 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62055853; called by muse, mutect2
- CSPP1 | c.1768A>G p.S590G (on ENST00000676605; = p.S549G on NM_024790.6) | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.07); catalogued as COSV51588726; called by muse, mutect2, varscan2
- CX3CR1 | c.639A>C p.R213S | Missense Mutation (SNP) | VAF 45/152 reads (30%) | SIFT tolerated (0.71); PolyPhen benign (0.265); catalogued as COSV64194584; called by muse, mutect2, varscan2
- CYC1 | c.469G>A p.G157S | Missense Mutation (SNP) | VAF 40/352 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778645997, COSV100010249; called by muse, mutect2, varscan2
- CYP11B2 | c.452C>A p.P151H | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as COSV59997011; called by muse, mutect2, varscan2
- DAB2 | c.865A>T p.T289S | Missense Mutation (SNP) | VAF 48/216 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57916919; called by mutect2, varscan2
- DCPS | c.902T>C p.V301A | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55011747; called by muse, mutect2, varscan2
- DGKK | c.3740A>G p.N1247S | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as rs1569543953, COSV65708722; called by muse, mutect2
- DLX5 | c.691C>A p.R231S | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.585); catalogued as COSV56031768, COSV56033712; called by muse, mutect2, varscan2
- DMD | c.1064T>G p.L355R | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55887993; called by muse, mutect2, varscan2
- DNAJC21 | c.476G>T p.C159F | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57761653; called by muse, mutect2, varscan2
- DNASE1L3 | c.655G>T p.D219Y | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59156840; called by muse, mutect2, varscan2
- DNASE2 | c.961C>T p.R321W | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1340314946, COSV52251015; called by muse, mutect2, varscan2
- DNTT | c.301C>A p.L101I | Missense Mutation (SNP) | VAF 41/160 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.051); catalogued as COSV64523388; called by muse, mutect2, varscan2
- DOP1B | c.5090G>C p.R1697T | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.114); catalogued as COSV67692864; called by muse, mutect2, varscan2
- DYNC1H1 | c.12203C>T p.S4068L | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV64139734; called by muse, mutect2, varscan2
- EDN3 | c.101C>T p.S34F | Missense Mutation (SNP) | VAF 89/126 reads (71%) | SIFT deleterious (0); PolyPhen benign (0.321); catalogued as COSV61109075; called by muse, mutect2, varscan2
- ENPP7 | c.764G>A p.R255Q | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs372623650; called by muse, mutect2, varscan2
- EYA1 | c.1054C>A p.P352T | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.26); catalogued as COSV100379801, COSV58168687; called by muse, mutect2, varscan2
- FCER2 | c.787C>T p.R263W | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.896); catalogued as rs1233484858, COSV60918037; called by muse, mutect2
- FER1L6 | c.1281G>T p.K427N | Missense Mutation (SNP) | VAF 12/222 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV67551630; called by muse, mutect2
- FREM1 | c.1285T>A p.S429T | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV63087372, COSV63087467; called by muse, mutect2, varscan2
- FYCO1 | c.466G>T p.E156* | Nonsense Mutation (SNP) | VAF 48/112 reads (43%) | catalogued as COSV56117866; called by muse, mutect2, varscan2
- GIMAP1 | c.70C>A p.Q24K | Missense Mutation (SNP) | VAF 92/332 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as COSV56189142; called by muse, varscan2
- GLCCI1 | c.1166A>T p.D389V | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56203640; called by muse, mutect2, varscan2
- GNPDA1 | c.201G>T p.K67N | Missense Mutation (SNP) | VAF 72/297 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as COSV60942811; called by muse, mutect2, varscan2
- GPR108 | c.1441G>A p.V481M (on ENST00000264080 / NM_001080452.1; = p.V239M on NM_020171.2) | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.895); catalogued as COSV51185991; called by muse, mutect2, varscan2
- HAS2 | c.103C>T p.Q35* | Nonsense Mutation (SNP) | VAF 8/160 reads (5%) | catalogued as COSV58265801; called by muse, mutect2
- HDAC4 | c.2988G>T p.E996D | Missense Mutation (SNP) | VAF 60/199 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV61871251; called by muse, mutect2, varscan2
- HEATR1 | c.509G>T p.G170V | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63979505; called by muse, mutect2, varscan2
- HMMR | c.435G>T p.R145S | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV62375079; called by muse, mutect2, varscan2
- HNRNPM | c.1297G>A p.E433K | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.057); catalogued as rs1323427555, COSV55311706, COSV55315430; called by muse, mutect2
- HNRNPUL1 | c.673G>T p.A225S | Missense Mutation (SNP) | VAF 41/148 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV54564933; called by muse, mutect2, varscan2
- IDH1 | c.1123G>T p.D375Y | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV61632657; called by muse, mutect2, varscan2
- IGHV3-33 | c.193G>C p.E65Q | Missense Mutation (SNP) | VAF 44/79 reads (56%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.662); catalogued as rs367591298; called by muse, mutect2, varscan2
- IGLL5 | c.379C>T p.L127F | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.821); catalogued as rs780858679, COSV101138662; called by muse, mutect2, varscan2
- IL21R | c.950A>G p.Y317C | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV61971617; called by muse, mutect2, varscan2
- IL31 | c.349C>T p.Q117* | Nonsense Mutation (SNP) | VAF 19/143 reads (13%) | catalogued as COSV65476522; called by muse, mutect2, varscan2
- INTS2 | c.2006T>C p.L669S | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as rs1356279244, COSV52154972; called by muse, mutect2
- INTS5 | c.1069G>T p.G357* | Nonsense Mutation (SNP) | VAF 26/83 reads (31%) | catalogued as COSV57952700; called by muse, mutect2, varscan2
- KANK2 | c.1111G>T p.G371C | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.417); catalogued as COSV62009034, COSV62010748; called by muse, mutect2, varscan2
- KCNC2 | c.1027G>T p.V343L | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as COSV54374412; called by muse, mutect2, varscan2
- KCTD13 | c.371A>C p.Y124S | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58160953; called by muse, mutect2, varscan2
- KLHDC10 | c.881T>A p.L294H | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV59053006; called by muse, mutect2, varscan2
- KLK2 | c.366G>T p.M122I | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1194200706, COSV57570285; called by muse, mutect2, varscan2
- KRT6B | c.871C>G p.L291V | Missense Mutation (SNP) | VAF 7/172 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV52885163, COSV52886427; called by muse, mutect2
- LGMN | c.41G>T p.G14V | Missense Mutation (SNP) | VAF 32/156 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.091); catalogued as COSV58404462; called by muse, varscan2
- LMBRD1 | c.259G>C p.A87P | Missense Mutation (SNP) | VAF 42/78 reads (54%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.498); catalogued as COSV65297283, COSV65298460; called by muse, mutect2, varscan2
- LRRC32 | c.966G>C p.L322F | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52634307; called by muse, mutect2, varscan2
- LRRTM1 | c.970G>T p.A324S | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.134); catalogued as COSV54444388; called by muse, mutect2
- MACF1 | c.14410C>T p.Q4804* (on ENST00000372915; = p.Q2737* on NM_012090.5) | Nonsense Mutation (SNP) | VAF 37/306 reads (12%) | catalogued as COSV57133148; called by muse, mutect2, varscan2
- MAF1 | c.669G>C p.E223D | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV59363660; called by muse, mutect2
- MAP2 | c.3513_3514insT p.E1172* | Frame Shift Ins (INS) | VAF 21/84 reads (25%) | catalogued as COSV99558303; called by mutect2, pindel, varscan2
- MDGA2 | c.2252G>T p.R751L (on ENST00000399232 / NM_001113498.2; = p.R453L on NM_182830.4) | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.972); catalogued as COSV62080622, COSV62094807, COSV62104364; called by muse, mutect2, varscan2
- MDH1B | c.314T>G p.M105R | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV65590632; called by muse, mutect2, varscan2
- MEGF8 | c.6102G>T p.W2034C (on ENST00000251268 / NM_001271938.2; = p.W1967C on NM_001410.3) | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52094037; called by muse, mutect2, varscan2
- MICAL3 | c.3702G>T p.R1234S | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as COSV71588783; called by muse, mutect2, varscan2
- MRGBP | c.470C>G p.S157C | Missense Mutation (SNP) | VAF 10/203 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV65111611; called by muse, mutect2
- MS4A14 | c.1969C>A p.H657N | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.036); catalogued as COSV55736604; called by muse, mutect2, varscan2
- MSH6 | c.3740C>G p.T1247S | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786204182, COSV52276876, COSV52284066; ClinVar: uncertain significance; called by muse, mutect2
- MUC16 | c.32638C>G p.P10880A | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.015); catalogued as rs1190936539, COSV67480173; called by muse, mutect2, varscan2
- MUC7 | c.695C>A p.P232Q | Missense Mutation (SNP) | VAF 69/189 reads (37%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs754099321, COSV59219458; called by muse, varscan2
- MYO16 | c.2736G>A p.M912I | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.124); catalogued as rs991866039, COSV51806826; called by muse, mutect2, varscan2
- MYOCD | c.2572C>G p.P858A | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.084); catalogued as COSV58504863, COSV58507950; called by muse, mutect2
- MYT1L | c.2368C>A p.P790T | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV67726669; called by muse, mutect2, varscan2
- NARF | c.587C>T p.S196F | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.443); catalogued as rs770103245, COSV59112871; called by muse, mutect2, varscan2
- NIPSNAP2 | c.363G>T p.Q121H | Missense Mutation (SNP) | VAF 43/147 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV59051952; called by muse, mutect2, varscan2
- NLRP2 | c.994C>A p.L332M | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54757826; called by muse, mutect2
- NRIP1 | c.1081G>T p.G361C | Missense Mutation (SNP) | VAF 55/162 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.621); catalogued as COSV100012346; called by muse, mutect2, varscan2
- NSMAF | c.1527G>C p.W509C | Missense Mutation (SNP) | VAF 41/420 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99232417, COSV99232438; called by muse, mutect2
- NTRK3 | c.1375C>G p.R459G | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as COSV58122146, COSV58132978; called by muse, mutect2, varscan2
- NUPR1 | c.67A>C p.S23R | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.351); catalogued as COSV100257117, COSV61405180; called by muse, mutect2, varscan2
- NXF1 | c.799-1G>T p.X267_splice | Splice Site (SNP) | VAF 14/61 reads (23%) | catalogued as COSV53675544; called by muse, mutect2, varscan2
- NXF1 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 19/186 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53675557; called by muse, mutect2, varscan2
- ODF1 | c.577G>T p.G193C | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV53433474; called by muse, mutect2, varscan2
- OR11L1 | c.160C>T p.R54* | Nonsense Mutation (SNP) | VAF 6/35 reads (17%) | catalogued as rs376918027; called by muse, mutect2, varscan2
- OR2L3 | c.880A>C p.K294Q | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV63455835; called by muse, mutect2, varscan2
- OR5K3 | c.401C>A p.T134N | Missense Mutation (SNP) | VAF 56/200 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.374); catalogued as COSV67350418; called by muse, mutect2, varscan2
- OR6K6 | c.561G>T p.E187D (on ENST00000368144; = p.E163D on NM_001005184.1) | Missense Mutation (SNP) | VAF 51/159 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV63744557; called by muse, mutect2, varscan2
- OR7G2 | c.907C>A p.P303T | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.56); PolyPhen benign (0.028); catalogued as COSV100560350; called by muse, mutect2, varscan2
- ORAI1 | c.712G>A p.A238T | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.072); catalogued as rs782448303, COSV57491404; called by muse, mutect2, varscan2
- OSMR | c.461A>T p.K154I | Missense Mutation (SNP) | VAF 38/174 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.051); catalogued as COSV57088586; called by muse, mutect2, varscan2
- OTOGL | c.2402G>A p.R801H (on ENST00000547103; = p.R792H on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.58); PolyPhen benign (0.005); catalogued as rs771349732, COSV72006817; called by muse, varscan2
- PASD1 | c.748T>G p.Y250D | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV64856495; called by muse, mutect2
- PBDC1 | c.370G>T p.D124Y | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV64896044; called by muse, mutect2, varscan2
- PCDHB4 | c.1297C>A p.Q433K | Missense Mutation (SNP) | VAF 36/164 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as rs559824378, COSV52024858; called by muse, mutect2, varscan2
- PCDHB7 | c.2048C>A p.S683* | Nonsense Mutation (SNP) | VAF 40/126 reads (32%) | catalogued as rs1554280360, COSV50772098, COSV50794392; called by muse, mutect2, varscan2
- PCDHGA2 | c.2262_2263insA p.H755Tfs*32 | Frame Shift Ins (INS) | VAF 45/183 reads (25%) | catalogued as COSV99532682; called by mutect2, pindel, varscan2
- PCDHGA4 | c.1038T>A p.Y346* | Nonsense Mutation (SNP) | VAF 7/28 reads (25%) | catalogued as COSV53992084; called by muse, mutect2, varscan2
- PCDHGB1 | c.2218A>T p.S740C | Missense Mutation (SNP) | VAF 29/172 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.832); catalogued as COSV53992067; called by muse, mutect2, varscan2
- PCSK1 | c.210C>G p.F70L | Missense Mutation (SNP) | VAF 5/117 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV60734707, COSV60736600; called by muse, mutect2
- PCSK5 | c.847G>C p.G283R | Missense Mutation (SNP) | VAF 53/291 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65092944; called by muse, mutect2, varscan2
- PDE6A | c.2567C>A p.S856Y | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as COSV54929654, COSV54932313; called by muse, mutect2, varscan2
- PDHA2 | c.1143G>T p.W381C | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1293790541, COSV54780540; called by muse, mutect2, varscan2
- PGK2 | c.933G>T p.W311C | Missense Mutation (SNP) | VAF 116/247 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as rs1377150771, COSV59164753; called by muse, mutect2, varscan2
- PHACTR4 | c.1889G>T p.R630M (on ENST00000373839 / NM_001350159.2; = p.R640M on NM_023923.4) | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV65784692; called by muse, mutect2, varscan2
- PJVK | c.527G>T p.G176V | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV57869765; called by muse, mutect2, varscan2
- PKP1 | c.1897G>T p.G633W | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs756541920, COSV55821168; called by muse, mutect2, varscan2
- PLCL1 | c.867G>T p.K289N | Missense Mutation (SNP) | VAF 9/143 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.756); catalogued as COSV70851486; called by muse, mutect2
- PLPPR1 | c.634A>G p.T212A | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (1); PolyPhen possibly damaging (0.814); catalogued as COSV66455612; called by muse, mutect2, varscan2
- PML | c.307G>T p.A103S | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.055); catalogued as rs570405596, COSV51450798; called by muse, mutect2, varscan2
- PMS1 | c.2574A>T p.L858F | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); catalogued as COSV59718598; called by muse, mutect2, varscan2
- POSTN | c.2038C>A p.P680T | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV101123374; called by mutect2, varscan2
- PRPF4B | c.1007G>T p.G336V | Missense Mutation (SNP) | VAF 73/131 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV61785003; called by muse, mutect2, varscan2
- PRR14 | c.1696G>A p.E566K | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV54912879; called by muse, mutect2
- PRSS36 | c.713C>G p.T238S | Missense Mutation (SNP) | VAF 37/152 reads (24%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.992); catalogued as COSV51638653; called by muse, mutect2, varscan2
- PTN | c.387del p.E130Nfs*15 | Frame Shift Del (DEL) | VAF 55/344 reads (16%) | catalogued as COSV100780791; called by mutect2, pindel, varscan2
- PTPRK | c.4180G>A p.E1394K (on ENST00000368215 / NM_001291984.2; = p.E1395K on NM_002844.4) | Missense Mutation (SNP) | VAF 31/215 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV63895745; called by muse, mutect2, varscan2
- PUS7 | c.1504G>A p.G502R | Missense Mutation (SNP) | VAF 59/261 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62677477; called by muse, mutect2, varscan2
- R3HCC1L | c.1375A>G p.T459A | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.077); catalogued as rs765663843, COSV54403570; called by muse, mutect2, varscan2
- RELN | c.4894T>A p.C1632S | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV59020662; called by muse, mutect2, varscan2
- RGS4 | c.39G>C p.L13F | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV63357819; called by muse, mutect2
- RHBDF2 | c.835G>T p.E279* | Nonsense Mutation (SNP) | VAF 52/132 reads (39%) | catalogued as COSV57421633; called by muse, mutect2, varscan2
- RIMS2 | c.2654-1G>C p.X885_splice (on ENST00000666250 / NM_001348490.2; = p.X693_splice on NM_014677.5 and 7 other RefSeq transcripts) | Splice Site (SNP) | VAF 102/396 reads (26%) | catalogued as COSV51702898; called by muse, mutect2, varscan2
- RNASE13 | c.375C>A p.Y125* | Nonsense Mutation (SNP) | VAF 23/211 reads (11%) | catalogued as COSV100409498; called by muse, mutect2, varscan2
- ROBO3 | c.1089C>A p.S363R | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs770920293, COSV67301821; called by muse, mutect2, varscan2
- RPGRIP1 | c.2830G>T p.G944W | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.624); catalogued as COSV99250580; called by muse, mutect2, varscan2
- RPS6KA2 | c.1063C>T p.R355W | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1394229232, COSV55822838; called by muse, mutect2, varscan2
- SAMD4A | c.1527G>T p.L509F | Missense Mutation (SNP) | VAF 142/373 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV51885076; called by muse, mutect2, varscan2
- SAMD9 | c.4586G>T p.R1529L | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.902); catalogued as COSV66076779; called by muse, mutect2, varscan2
- SAP130 | c.2395+2T>G p.X799_splice | Splice Site (SNP) | VAF 14/94 reads (15%) | catalogued as COSV99384221; called by muse, mutect2, varscan2
- SART1 | c.1699C>G p.P567A | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as COSV56712972; called by muse, mutect2, varscan2
- SERPINA4 | c.235C>A p.P79T | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54069375; called by muse, mutect2, varscan2
- SH3PXD2A | c.2546G>C p.S849T (on ENST00000369774 / NM_001365079.1; = p.S821T on NM_014631.2) | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.322); catalogued as COSV100280413, COSV60118838; called by muse, mutect2, varscan2
- SHANK2 | c.1870G>C p.E624Q | Missense Mutation (SNP) | VAF 30/254 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as COSV53609992; called by muse, mutect2, varscan2
- SHISA2 | c.773C>T p.P258L | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.118); catalogued as COSV100096290; called by muse, mutect2, varscan2
- SIGLECL1 | c.214C>A p.L72I | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV57063868; called by muse, mutect2, varscan2
- SLC26A5 | c.1798G>A p.D600N | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT tolerated (0.84); PolyPhen benign (0.026); catalogued as rs768005303, COSV59704138; called by muse, mutect2, varscan2
- SLCO1A2 | c.167C>G p.S56C | Missense Mutation (SNP) | VAF 40/140 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56606812; called by muse, mutect2, varscan2
- SMARCA2 | c.1012G>T p.D338Y | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV61810226; called by muse, mutect2, varscan2
- SORCS2 | c.2845G>C p.D949H | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV61177766; called by muse, mutect2, varscan2
- SPAG9 | c.1519G>C p.E507Q (on ENST00000262013 / NM_001130528.3; = p.E493Q on NM_003971.6) | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56230837, COSV56239833; called by muse, mutect2, varscan2
- SPSB2 | c.254C>A p.S85* | Nonsense Mutation (SNP) | VAF 23/56 reads (41%) | catalogued as COSV99222813; called by muse, mutect2, varscan2
- ST6GAL2 | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 8/54 reads (15%) | PolyPhen probably damaging (0.978); catalogued as rs372148383; called by muse, mutect2, varscan2
- STAG3 | c.3454C>A p.P1152T | Missense Mutation (SNP) | VAF 37/178 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.115); catalogued as COSV57933003; called by muse, mutect2, varscan2
- SYMPK | c.2601C>G p.V867= | Splice Region (SNP) | VAF 3/35 reads (9%) | catalogued as COSV55613822; called by muse, mutect2
- TAFA3 | c.402G>T p.*134Yext*12 | Nonstop Mutation (SNP) | VAF 16/67 reads (24%) | catalogued as COSV62625077; called by muse, mutect2, varscan2
- TARBP2 | c.709G>A p.E237K (on ENST00000266987 / NM_134323.2; = p.E216K on NM_004178.4) | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.355); catalogued as COSV57200240; called by muse, mutect2
- TBX5 | c.1221C>A p.Y407* | Nonsense Mutation (SNP) | VAF 19/73 reads (26%) | catalogued as CM1413705, COSV59863370; called by muse, mutect2, varscan2
- TENM1 | c.4827G>T p.W1609C | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.964); catalogued as COSV64438073; called by muse, mutect2, varscan2
- THEM5 | c.634C>T p.Q212* | Nonsense Mutation (SNP) | VAF 47/112 reads (42%) | catalogued as COSV100917224, COSV64313096; called by muse, mutect2, varscan2
- TIAM1 | c.2649A>T p.L883F | Missense Mutation (SNP) | VAF 124/325 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV54563707; called by muse, mutect2, varscan2
- TMEM252 | c.337C>A p.P113T | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.173); catalogued as COSV101051102; called by muse, mutect2, varscan2
- TMPRSS15 | c.2032G>T p.V678L | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.167); catalogued as rs755808165, COSV53044324; called by muse, mutect2, varscan2
- TNMD | c.899G>T p.C300F | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV65977502; called by muse, mutect2, varscan2
- TPH1 | c.880G>T p.G294C | Missense Mutation (SNP) | VAF 45/136 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV51459229; called by muse, mutect2, varscan2
- TRAF3 | c.1235C>T p.A412V | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.412); catalogued as COSV100693483; called by muse, mutect2, varscan2
- TRIM10 | c.1246G>T p.G416C | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.739); catalogued as COSV100939648; called by muse, mutect2, varscan2
- TRPM3 | c.1078C>G p.P360A (on ENST00000357533 / NM_001366142.2; = p.P205A on NM_020952.6) | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV62472324; called by muse, mutect2, varscan2
- TRPM6 | c.5641G>T p.G1881W | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62517125; called by muse, mutect2, varscan2
- TRPV6 | c.354G>T p.M118I | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV63891310, COSV63892742; called by muse, mutect2, varscan2
- TRRAP | c.10136G>T p.G3379V (on ENST00000359863 / NM_001244580.1; = p.G3350V on NM_003496.3) | Missense Mutation (SNP) | VAF 67/251 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV62850112; called by muse, mutect2, varscan2
- TTN | c.19041A>T p.T6347= (on ENST00000591111; = p.T5420= on NM_133378.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 20/268 reads (7%) | catalogued as COSV60206904; called by muse, mutect2
- TUBA3C | c.394C>A p.L132M | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.692); catalogued as COSV67139688; called by muse, mutect2, varscan2
- TWIST1 | c.380C>T p.A127V | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM000118, CM060097, COSV54250834; called by muse, mutect2, varscan2
- UIMC1 | c.2129A>T p.K710I | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV65894371; called by muse, mutect2
- UMPS | c.1285G>A p.G429S | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM971562, COSV51738228; called by muse, mutect2, varscan2
- URI1 | c.592G>C p.D198H | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.293); catalogued as COSV56351945; called by muse, mutect2
- USP47 | c.3907G>T p.V1303F (on ENST00000399455 / NM_001372095.1; = p.V1215F on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/156 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.353); catalogued as COSV59694392; called by muse, mutect2, varscan2
- WDR54 | c.362T>G p.V121G | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV51965057; called by muse, mutect2, varscan2
- XPNPEP3 | c.27G>C p.K9N | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.117); catalogued as COSV99344009; called by muse, mutect2, varscan2
- XYLT1 | c.1868G>C p.G623A | Missense Mutation (SNP) | VAF 51/180 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV54491099; called by muse, mutect2, varscan2
- ZBTB3 | c.1190T>A p.L397Q | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV67361579; called by muse, mutect2, varscan2
- ZFHX4 | c.6877G>T p.D2293Y | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV50738992, COSV51476477; called by muse, mutect2, varscan2
- ZFHX4 | c.7125C>A p.N2375K | Missense Mutation (SNP) | VAF 88/294 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.027); catalogued as COSV51443681, COSV51476529; called by muse, mutect2, varscan2
- ZNF235 | c.901A>G p.S301G | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV52157588; called by muse, mutect2
- ZNF418 | c.392A>T p.Y131F | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.287); catalogued as COSV101268893; called by muse, mutect2
- ZNF442 | c.682G>T p.E228* | Nonsense Mutation (SNP) | VAF 37/160 reads (23%) | catalogued as COSV54422479; called by muse, mutect2, varscan2
- ZNF536 | c.292G>T p.G98W | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62829439; called by muse, mutect2
- ZNF586 | c.106C>A p.Q36K | Missense Mutation (SNP) | VAF 50/280 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV66972574, COSV66972580; called by muse, mutect2, varscan2
- ZNF644 | c.3538A>T p.M1180L | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61349140; called by muse, mutect2, varscan2
- ZNF697 | c.266G>C p.G89A | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV101360071; called by muse, mutect2, varscan2
- ZNF875 | c.1671G>T p.E557D | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.142); catalogued as COSV100183125; called by muse, mutect2, varscan2
- ADGRL3 | c.468_469del p.Q157Kfs*4 (on ENST00000506720 / NM_001322402.2; = p.Q89Kfs*4 on NM_015236.6) | Frame Shift Del (DEL) | VAF 6/31 reads (19%) | called by pindel, varscan2
- FCGBP | c.9103G>T p.A3035S | Missense Mutation (SNP) | VAF 27/344 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.91); called by muse, mutect2
- KMT2A | c.10992dup p.P3665Tfs*8 | Frame Shift Ins (INS) | VAF 36/120 reads (30%) | called by mutect2, pindel, varscan2
- LAD1 | c.550del p.S184Pfs*35 | Frame Shift Del (DEL) | VAF 52/182 reads (29%) | called by mutect2, pindel, varscan2
- MYO1H | c.1087del p.A363Qfs*20 | Frame Shift Del (DEL) | VAF 27/115 reads (23%) | called by mutect2, pindel, varscan2
- MYO6 | c.1624del p.H542Tfs*67 | Frame Shift Del (DEL) | VAF 8/74 reads (11%) | called by mutect2, pindel, varscan2
- NLRP10 | c.1644del p.F548Lfs*8 | Frame Shift Del (DEL) | VAF 22/125 reads (18%) | called by mutect2, pindel, varscan2
- OTUD6A | c.157G>T p.A53S | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- POSTN | c.2039del p.P680Qfs*5 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | called by mutect2, varscan2
- PXDNL | c.937del p.E313Kfs*21 | Frame Shift Del (DEL) | VAF 44/198 reads (22%) | called by mutect2, pindel, varscan2
- TGFBI | c.245del p.Y82Sfs*47 | Frame Shift Del (DEL) | VAF 35/184 reads (19%) | called by mutect2, pindel, varscan2
- ABCB9 | c.1810C>T p.L604= (on ENST00000280560 / NM_019625.4; = p.L561= on NM_019624.3) | Silent (SNP) | VAF 5/77 reads (6%) | catalogued as COSV54893256; called by muse, mutect2
- ALDH8A1 | c.426G>T p.R142= | Silent (SNP) | VAF 30/73 reads (41%) | catalogued as rs541243826, COSV55643037; called by muse, mutect2, varscan2
- ARF5 | c.474C>T p.T158= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as COSV50001651; called by muse, mutect2, varscan2
- ASTN1 | c.3435C>T p.C1145= | Silent (SNP) | VAF 28/101 reads (28%) | catalogued as rs1180197095, COSV62501205; called by muse, mutect2, varscan2
- BCAR1 | c.1623T>A p.L541= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as COSV50792625; called by muse, mutect2, varscan2
- BCL6 | c.1065C>A p.I355= | Silent (SNP) | VAF 27/241 reads (11%) | catalogued as COSV51654172; called by muse, mutect2, varscan2
- CFAP44 | c.1395C>A p.L465= | Silent (SNP) | VAF 8/93 reads (9%) | catalogued as COSV55613903; called by muse, mutect2
- CLCN1 | c.2361C>A p.T787= | Silent (SNP) | VAF 29/133 reads (22%) | catalogued as COSV58372439; called by muse, mutect2, varscan2
- CRYGS | c.57T>A p.R19= | Silent (SNP) | VAF 26/68 reads (38%) | catalogued as COSV57192729; called by muse, mutect2, varscan2
- CSF2RB | c.1728C>A p.A576= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV53259509, COSV53260216; called by muse, mutect2, varscan2
- CTAGE1 | c.85T>C p.L29= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as COSV66944091; called by muse, mutect2, varscan2
- DLGAP4 | c.387C>T p.A129= | Silent (SNP) | VAF 26/300 reads (9%) | catalogued as COSV59420834; called by muse, mutect2
- DNA2 | c.1323C>T p.F441= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as rs535129572, COSV64429371; called by muse, mutect2, varscan2
- DNAJB9 | c.555C>G p.T185= | Silent (SNP) | VAF 10/114 reads (9%) | catalogued as COSV99974408; called by muse, mutect2
- FAM71E1 | c.303G>A p.Q101= | Silent (SNP) | VAF 13/23 reads (57%) | catalogued as COSV58542772; called by muse, mutect2, varscan2
- FAT4 | c.10239G>T p.V3413= | Silent (SNP) | VAF 14/238 reads (6%) | catalogued as COSV58698516; called by muse, mutect2
- GPR35 | c.624G>A p.Q208= | Silent (SNP) | VAF 22/52 reads (42%) | catalogued as COSV100166356; called by muse, mutect2, varscan2
- GRM1 | c.2259G>C p.V753= | Silent (SNP) | VAF 59/155 reads (38%) | catalogued as COSV51210059; called by muse, mutect2, varscan2
- HTR7 | c.501G>T p.T167= | Silent (SNP) | VAF 18/26 reads (69%) | catalogued as COSV99519098, COSV99519208; called by muse, mutect2, varscan2
- IDH1 | c.882G>T p.V294= | Silent (SNP) | VAF 28/95 reads (29%) | catalogued as COSV61632663; called by muse, mutect2, varscan2
- IGSF8 | c.555C>A p.G185= | Silent (SNP) | VAF 6/89 reads (7%) | catalogued as COSV58758715; called by muse, mutect2
- KIF5A | c.2493C>A p.S831= | Silent (SNP) | VAF 53/171 reads (31%) | catalogued as COSV54056976; called by muse, mutect2, varscan2
- KLHDC4 | c.1236G>T p.R412= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV54510036; called by muse, mutect2, varscan2
- KLHL21 | c.1461G>T p.P487= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV100887202, COSV100887217; called by muse, mutect2, varscan2
- LRRK1 | c.51G>C p.P17= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as COSV52620384, COSV52626538; called by muse, mutect2, varscan2
- MGAM | c.2292C>A p.L764= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV72075164, COSV72076159; called by muse, mutect2, varscan2
- N4BP2 | c.822C>T p.C274= | Silent (SNP) | VAF 20/120 reads (17%) | catalogued as rs749669817, COSV54704708; called by muse, mutect2, varscan2
- NBAS | c.3838C>A p.R1280= | Silent (SNP) | VAF 19/108 reads (18%) | catalogued as COSV55730732; called by muse, mutect2, varscan2
- NEFH | c.1137C>A p.A379= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as rs372676194, COSV60218876; called by muse, mutect2, varscan2
- OLFML1 | c.624C>A p.I208= | Silent (SNP) | VAF 25/65 reads (38%) | catalogued as COSV55080081; called by muse, mutect2, varscan2
- OR2T2 | c.441C>G p.V147= | Silent (SNP) | VAF 40/225 reads (18%) | catalogued as COSV100737585, COSV100737724; called by muse, mutect2, varscan2
- PCDH10 | c.219G>T p.L73= | Silent (SNP) | VAF 8/138 reads (6%) | catalogued as COSV52099560; called by muse, mutect2
- PDE1C | c.432T>C p.Y144= | Silent (SNP) | VAF 29/62 reads (47%) | catalogued as rs768110155, COSV58521217; called by muse, mutect2, varscan2
- PKHD1L1 | c.11400A>T p.P3800= | Silent (SNP) | VAF 46/644 reads (7%) | catalogued as COSV65748082; called by muse, mutect2
- PPP1R16B | c.1527G>T p.T509= | Silent (SNP) | VAF 23/45 reads (51%) | catalogued as COSV55376582, COSV55379692; called by muse, mutect2, varscan2
- PPP2R3C | c.1323A>C p.A441= | Silent (SNP) | VAF 22/103 reads (21%) | catalogued as COSV54834016; called by muse, mutect2, varscan2
- PRMT2 | c.219G>T p.A73= | Silent (SNP) | VAF 55/128 reads (43%) | catalogued as COSV99388533; called by muse, mutect2, varscan2
- PRRC2C | c.1977G>T p.P659= (on ENST00000367742; = p.P657= on NM_015172.4) | Silent (SNP) | VAF 68/281 reads (24%) | catalogued as COSV58909014; called by muse, mutect2, varscan2
- PSG4 | c.1026C>G p.T342= | Silent (SNP) | VAF 86/318 reads (27%) | catalogued as rs146368793, COSV54938302; called by muse, mutect2, varscan2
- RYR2 | c.6093C>A p.S2031= | Silent (SNP) | VAF 26/108 reads (24%) | catalogued as COSV63700024; called by muse, mutect2, varscan2
- SASS6 | c.1398T>C p.N466= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV54929158; called by muse, mutect2, varscan2
- SCRIB | c.3873G>A p.K1291= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as rs555968352, COSV57590550; called by muse, mutect2
- SH2D5 | c.786G>A p.S262= (on ENST00000444387 / NM_001103161.2; = p.S178= on NM_001103160.2) | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs1334191027, COSV100903797; called by muse, mutect2, varscan2
- TASOR2 | c.2922A>G p.Q974= | Silent (SNP) | VAF 6/93 reads (6%) | catalogued as rs1209796223, COSV60168620; called by muse, mutect2
- TECRL | c.870C>A p.P290= | Silent (SNP) | VAF 20/71 reads (28%) | catalogued as COSV67088976; called by muse, mutect2, varscan2
- TLCD3B | c.18G>T p.V6= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as COSV54227701; called by muse, mutect2, varscan2
- TNRC6B | c.1185C>T p.P395= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as rs1331711695, COSV57302208; called by muse, mutect2, varscan2
- UGGT2 | c.1431C>T p.S477= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as COSV65072742; called by muse, mutect2, varscan2
- UGT1A7 | c.270C>T p.F90= | Silent (SNP) | VAF 60/208 reads (29%) | catalogued as COSV60845961; called by muse, varscan2
- XPC | c.1269G>C p.R423= | Silent (SNP) | VAF 86/302 reads (28%) | catalogued as COSV99542113; called by muse, mutect2, varscan2
- ZNF202 | c.1323C>T p.A441= | Silent (SNP) | VAF 50/152 reads (33%) | catalogued as rs750005789, COSV60247810; called by muse, mutect2, varscan2
- AL590867.2 | n.361G>T | RNA (SNP) | VAF 46/126 reads (37%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65502211 G>C | 5'Flank (SNP) | VAF 16/66 reads (24%) | catalogued as rs1211322691; called by muse, mutect2, varscan2
- BCL2A1 | c.420+3031T>A | Intron (SNP) | VAF 13/55 reads (24%) | catalogued as rs994903767, COSV99144317; called by muse, mutect2, varscan2
- SYCE1 | chr10:133554318 G>T | 3'Flank (SNP) | VAF 27/112 reads (24%) | catalogued as COSV58218393; called by muse, mutect2, varscan2
